Somatic mutation profile of tumor specimen MP2PRT-PARWTB-TBP1-A (aliquot MP2PRT-PARWTB-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARWTB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,419 days).
Specimen MP2PRT-PARWTB-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfe1df96-69b7-4bc1-b131-906ce4ee073f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWTB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWTB-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7804effc-8ac6-4486-be2b-808ad512f244

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 58/408 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs761682028, COSV100746671; called by muse, mutect2, varscan2
- CARD11 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs761547989, COSV100829287, COSV62756309; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 68/576 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); catalogued as rs767513792, COSV62566498; called by muse, mutect2, varscan2
- INPP4A | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766419021, COSV50784947; called by muse, mutect2, varscan2
- KCNG1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 65/383 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.057); catalogued as COSV65370146; called by muse, mutect2, varscan2
- KRT10 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 67/529 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs771197683, COSV54089020, COSV54089234; called by muse, mutect2, varscan2
- MYF5 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 66/421 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356108; called by muse, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- PAPPA | c.2933A>G p.E978G | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60290236; called by muse, mutect2, varscan2
- FGL1 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAX5 | c.307A>T p.K103* | Nonsense Mutation (SNP) | VAF 67/566 reads (12%) | called by muse, mutect2, varscan2
- TECTA | c.3908T>G p.L1303R | Missense Mutation (SNP) | VAF 82/577 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FBN3 | c.6813C>T p.T2271= | Silent (SNP) | VAF 72/480 reads (15%) | catalogued as rs772027708; called by muse, mutect2, varscan2
- MGAT5B | c.1548G>A p.P516= (on ENST00000569840 / NM_001199172.2; = p.P514= on NM_144677.3) | Silent (SNP) | VAF 66/457 reads (14%) | catalogued as rs138623883; called by muse, mutect2, varscan2
- RALYL | c.465G>A p.P155= | Silent (SNP) | VAF 57/445 reads (13%) | catalogued as rs370262365; called by muse, mutect2, varscan2
- SYT3 | c.1587C>T p.N529= | Silent (SNP) | VAF 60/544 reads (11%) | catalogued as rs1366824485, COSV100144101; called by muse, mutect2, varscan2
